Somatic mutation profile of tumor specimen TCGA-PK-A5HB-01A (aliquot TCGA-PK-A5HB-01A-11D-A29I-10) from TCGA case TCGA-PK-A5HB, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 63.8 years (23,293 days).
Specimen TCGA-PK-A5HB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 766c0d4e-f178-4fa3-97c4-955e08afad2d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-PK-A5HB-11A (Solid Tissue Normal), aliquot TCGA-PK-A5HB-11A-11D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78e6f9e2-4906-41d9-b474-0fe4c7ac3a91

The open-access MAF lists 1,192 somatic variants for this specimen: 879 protein-altering or splice-affecting, 291 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 707, Silent 291, Frame Shift Del 70, Nonsense Mutation 37, Frame Shift Ins 34, Splice Site 15, Intron 12, Splice Region 7, In Frame Del 6, RNA 4, 3'Flank 3, 3'UTR 2.

Variants (750 of 1,192; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALOXE3 | c.631C>T p.R211* | Nonsense Mutation (SNP) | VAF 109/144 reads (76%) | catalogued as rs141340759, COSV59074643; ClinVar: pathogenic; called by muse, varscan2
- ASPM | c.5149del p.I1717* | Frame Shift Del (DEL) | VAF 18/54 reads (33%) | catalogued as rs199422167, CD077387; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- COL18A1 | c.3918dup p.G1307Rfs*9 (on ENST00000359759 / NM_130444.3; = p.G1072Rfs*9 on NM_030582.4) | Frame Shift Ins (INS) | VAF 32/90 reads (36%) | catalogued as rs749009747; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CRYGD | c.475del p.A159Pfs*9 | Frame Shift Del (DEL) | VAF 34/104 reads (33%) | catalogued as rs764945940; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- FASTKD2 | c.965C>T p.P322L | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748507111, COSV52697783; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- IMPDH1 | c.673G>A p.D225N (on ENST00000470772 / NM_001142573.2; = p.D311N on NM_000883.4) | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); catalogued as rs121912550, CM020283; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LRPPRC | c.3147del p.A1051Hfs*6 | Frame Shift Del (DEL) | VAF 33/68 reads (49%) | catalogued as rs769022521; ClinVar: pathogenic; called by mutect2, varscan2
- MLH1 | c.1672G>T p.E558* | Nonsense Mutation (SNP) | VAF 30/40 reads (75%) | catalogued as rs63751081, CM990857; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 30/74 reads (41%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- NF1 | c.6004C>T p.Q2002* (on ENST00000358273 / NM_001042492.3; = p.Q1981* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 26/39 reads (67%) | catalogued as rs1567615941, CS054215; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NIPBL | c.64+1G>A p.X22_splice | Splice Site (SNP) | VAF 25/62 reads (40%) | catalogued as rs587784009, CS042837, COSV56965837; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SPTAN1 | c.2224C>T p.R742C | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); catalogued as rs780658554; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.919+1G>T p.X307_splice | Splice Site (SNP) | VAF 54/62 reads (87%) | hotspot (GDC flag); catalogued as rs1131691039, CD920913, CS107068, CS120864, COSV52683145, COSV52775982, COSV52814989; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ABCC2 | c.3409G>A p.V1137I | Missense Mutation (SNP) | VAF 87/212 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.116); catalogued as rs771168840; called by muse, mutect2, varscan2
- ABCG5 | c.1528del p.H510Tfs*2 | Frame Shift Del (DEL) | VAF 96/248 reads (39%) | catalogued as rs1404218188, CD162022, CM074664; called by mutect2, pindel, varscan2
- ACP7 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1420784066, COSV104402658; called by muse, mutect2, varscan2
- ADAM21 | c.2051del p.L684Cfs*3 | Frame Shift Del (DEL) | VAF 125/354 reads (35%) | catalogued as rs546931496; called by mutect2, pindel, varscan2
- ADGRB2 | c.3775G>A p.V1259I | Missense Mutation (SNP) | VAF 82/179 reads (46%) | SIFT tolerated (0.84); PolyPhen benign (0.014); catalogued as rs1311382311; called by muse, mutect2, varscan2
- ADGRB2 | c.3563C>T p.A1188V | Missense Mutation (SNP) | VAF 15/440 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1319739302; called by muse, mutect2
- ADGRG4 | c.4865dup p.N1622Kfs*62 | Frame Shift Ins (INS) | VAF 41/66 reads (62%) | catalogued as COSV99796635; called by mutect2, pindel, varscan2
- ADGRL1 | c.4330C>T p.R1444W (on ENST00000340736 / NM_001008701.3; = p.R1439W on NM_014921.5) | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs754657629, COSV61565209; called by muse, mutect2, varscan2
- ADGRV1 | c.7645A>G p.N2549D | Missense Mutation (SNP) | VAF 64/138 reads (46%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.979); catalogued as rs911743263; called by muse, mutect2, varscan2
- AGK | c.628C>T p.R210* | Nonsense Mutation (SNP) | VAF 32/77 reads (42%) | catalogued as rs368565785; called by muse, mutect2, varscan2
- AIFM3 | c.1741C>T p.R581W | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as rs1325530847, COSV53151195; called by muse, mutect2, varscan2
- AKAP12 | c.3876A>G p.I1292M | Missense Mutation (SNP) | VAF 99/218 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs749174370; called by muse, mutect2, varscan2
- AL669918.1 | c.2206C>T p.P736S | Missense Mutation (SNP) | VAF 52/148 reads (35%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.139); catalogued as rs201263357; called by muse, mutect2, varscan2
- ALMS1 | c.8849C>A p.P2950H | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.108); catalogued as rs777913623; called by muse, mutect2, varscan2
- ALX3 | c.313del p.Q105Sfs*88 | Frame Shift Del (DEL) | VAF 24/64 reads (38%) | catalogued as rs759127084; called by mutect2, pindel, varscan2
- AMER3 | c.2317C>T p.Q773* | Nonsense Mutation (SNP) | VAF 69/158 reads (44%) | catalogued as COSV100365865; called by muse, mutect2, varscan2
- ANGPT4 | c.288C>A p.N96K | Missense Mutation (SNP) | VAF 68/81 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1251171131; called by muse, mutect2, varscan2
- ANGPTL4 | c.1022G>A p.C341Y | Missense Mutation (SNP) | VAF 74/170 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1296289658; called by muse, mutect2, varscan2
- ANK1 | c.1910C>T p.T637M | Missense Mutation (SNP) | VAF 42/57 reads (74%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs769870526, COSV55878317; called by muse, mutect2, varscan2
- ANKRD30A | c.3385G>A p.E1129K (on ENST00000611781; = p.E1073K on NM_052997.2) | Missense Mutation (SNP) | VAF 83/208 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as COSV64607971; called by muse, mutect2, varscan2
- ANKS1A | c.959del p.P320Hfs*25 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | catalogued as COSV64461548; called by mutect2, pindel, varscan2
- APEX1 | c.60G>A p.E20= | Splice Region (SNP) | VAF 10/23 reads (43%) | catalogued as rs753254929; called by muse, varscan2
- ARHGEF4 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 103/127 reads (81%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as COSV58117128; called by muse, mutect2, varscan2
- ASCC2 | c.1579C>T p.P527S | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.255); catalogued as rs747467412; called by muse, mutect2, varscan2
- ATP6V1E2 | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.378); catalogued as COSV60576827; called by muse, mutect2, varscan2
- B3GALT2 | c.1175A>G p.K392R | Missense Mutation (SNP) | VAF 59/126 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0.074); catalogued as COSV66463768; called by muse, mutect2, varscan2
- BBS4 | c.1554G>C p.E518D | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs752394112; called by muse, mutect2, varscan2
- BNC2 | c.1853T>A p.M618K | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV66160127; called by muse, mutect2, varscan2
- BRD7 | c.830A>G p.E277G | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV67158427; called by muse, mutect2, varscan2
- BTRC | c.1780dup p.R594Pfs*27 (on ENST00000370187 / NM_033637.4; = p.R558Pfs*27 on NM_003939.5) | Frame Shift Ins (INS) | VAF 40/163 reads (25%) | catalogued as rs774921343; called by mutect2, varscan2
- C15orf39 | c.563G>A p.G188D | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV62296698; called by muse, mutect2, varscan2
- C4B | c.2554C>T p.R852W | Missense Mutation (SNP) | VAF 163/253 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs201414896; called by muse, mutect2, varscan2
- C6orf118 | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.091); catalogued as COSV57812462, COSV57814288; called by muse, mutect2
- C6orf15 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 53/118 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as rs560033699; called by muse, mutect2, varscan2
- CACNA1B | c.1159G>A p.G387R | Missense Mutation (SNP) | VAF 63/147 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.349); catalogued as COSV53138822; called by muse, mutect2, varscan2
- CALML6 | c.269A>T p.N90I | Missense Mutation (SNP) | VAF 86/205 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs200415259; called by muse, mutect2, varscan2
- CAMSAP2 | c.4309del p.M1437* (on ENST00000236925 / NM_001297707.2; = p.M1426* on NM_203459.3) | Frame Shift Del (DEL) | VAF 32/87 reads (37%) | catalogued as rs1375954479; called by mutect2, pindel, varscan2
- CARD10 | c.2366G>A p.R789H | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs776297419; called by muse, mutect2, varscan2
- CCDC185 | c.1372C>T p.R458W | Missense Mutation (SNP) | VAF 106/257 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.067); catalogued as rs1012767484, COSV64821931; called by muse, mutect2, varscan2
- CCDC73 | c.1913del p.N638Ifs*18 | Frame Shift Del (DEL) | VAF 38/49 reads (78%) | catalogued as rs762553129; called by mutect2, varscan2
- CCIN | c.841G>A p.V281M | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs150485511; called by muse, mutect2, varscan2
- CD19 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 45/84 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.137); catalogued as COSV61187800; called by muse, mutect2, varscan2
- CDC16 | c.1561C>T p.H521Y | Missense Mutation (SNP) | VAF 71/90 reads (79%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs754062932; called by muse, mutect2, varscan2
- CEP170B | c.1255C>T p.R419C (on ENST00000453495; = p.R348C on NM_015005.3) | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.63); catalogued as rs372246157; called by muse, mutect2, varscan2
- CEP170B | c.2153G>A p.S718N (on ENST00000453495; = p.S647N on NM_015005.3) | Missense Mutation (SNP) | VAF 66/168 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.189); catalogued as rs898905234; called by muse, mutect2, varscan2
- CEP83 | c.1658A>G p.Y553C | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs1445746147; called by muse, mutect2, varscan2
- CLDN9 | c.319T>C p.C107R | Missense Mutation (SNP) | VAF 70/215 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs199692917; called by muse, varscan2
- CLEC16A | c.3134C>T p.A1045V | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs1000161528; called by muse, mutect2, varscan2
- CLEC4C | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 25/31 reads (81%) | SIFT tolerated (0.34); PolyPhen benign (0.354); catalogued as COSV63583273; called by muse, mutect2, varscan2
- CLTB | c.440T>C p.V147A | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV60044829; called by muse, mutect2, varscan2
- COA7 | c.115C>T p.R39W | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs768084335, COSV101034460; called by mutect2, varscan2
- COG5 | c.2354A>G p.E785G (on ENST00000347053 / NM_001379512.1; = p.E806G on NM_006348.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1337266829; called by muse, mutect2, varscan2
- COPS6 | c.589C>T p.R197C | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1355680735; called by muse, mutect2
- CROT | c.614T>C p.V205A | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1406444255; called by muse, mutect2, varscan2
- DDB1 | c.154G>A p.V52I | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs868415564; called by muse, mutect2, varscan2
- DEAF1 | c.688C>T p.Q230* | Nonsense Mutation (SNP) | VAF 70/107 reads (65%) | catalogued as COSV100102394; called by muse, mutect2, varscan2
- DGKA | c.2176dup p.R726Pfs*79 | Frame Shift Ins (INS) | VAF 40/100 reads (40%) | catalogued as rs748318989; called by mutect2, varscan2
- DIO2 | c.56del p.F19Sfs*23 | Frame Shift Del (DEL) | VAF 12/83 reads (14%) | catalogued as rs148778534; called by mutect2, pindel, varscan2
- DIP2C | c.1652G>A p.G551D | Missense Mutation (SNP) | VAF 123/287 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs935304052, COSV55155731; called by muse, mutect2, varscan2
- DNA2 | c.2335del p.S779Hfs*6 | Frame Shift Del (DEL) | VAF 28/60 reads (47%) | catalogued as rs745893364; called by mutect2, varscan2
- DNAH10 | c.11716G>A p.V3906M (on ENST00000409039; = p.V3845M on NM_207437.3) | Missense Mutation (SNP) | VAF 147/341 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.394); catalogued as rs774809074; called by muse, varscan2
- DNAH17 | c.9856A>T p.I3286F | Missense Mutation (SNP) | VAF 49/61 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs1204965821; called by muse, mutect2, varscan2
- DNAH7 | c.3770del p.N1257Ifs*11 | Frame Shift Del (DEL) | VAF 138/306 reads (45%) | catalogued as rs34468832; called by mutect2, varscan2
- DOCK10 | c.5440T>C p.Y1814H | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV99291256; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 38/45 reads (84%) | catalogued as rs782552436; called by mutect2, varscan2
- DOCK5 | c.2105C>T p.S702L | Missense Mutation (SNP) | VAF 44/55 reads (80%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as rs1459980969; called by muse, mutect2, varscan2
- DOP1A | c.5290A>G p.I1764V | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (1); PolyPhen possibly damaging (0.891); catalogued as rs756793163; called by muse, mutect2, varscan2
- DPYD | c.544dup p.M182Nfs*3 | Frame Shift Ins (INS) | VAF 34/82 reads (41%) | catalogued as rs754785410; called by mutect2, varscan2
- DUS4L | c.923T>C p.I308T | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as rs1241020197; called by muse, mutect2, varscan2
- DUSP7 | c.664delinsAA p.D222Kfs*79 | Frame Shift Ins (INS) | VAF 63/160 reads (39%) | catalogued as COSV56589052; called by mutect2*, pindel, varscan2*
- EARS2 | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.975); catalogued as rs762685823, COSV101492151, COSV71942960; ClinVar: uncertain significance; called by muse, varscan2
- EFCAB14 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 93/235 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs763840513; called by muse, mutect2, varscan2
- EGR4 | c.1438G>A p.A480T (on ENST00000545030; = p.A377T on NM_001965.4) | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.162); catalogued as rs908712759; called by muse, mutect2
- EIPR1 | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 126/262 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs374023297; called by muse, mutect2, varscan2
- ELAPOR1 | c.2237del p.P746Qfs*3 | Frame Shift Del (DEL) | VAF 43/108 reads (40%) | catalogued as rs746129223; called by mutect2, pindel, varscan2
- EPHA2 | c.1498G>A p.D500N | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.078); catalogued as rs770339373; called by muse, varscan2
- EPHB6 | c.818G>A p.G273E | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1279498487, COSV101236001, COSV67418455; called by muse, mutect2, varscan2
- ERBB4 | c.653A>G p.D218G | Missense Mutation (SNP) | VAF 103/261 reads (39%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs890173173; called by muse, varscan2
- ERCC1 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs764307683; called by muse, mutect2, varscan2
- FAM171B | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 64/127 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs144563922; called by muse, mutect2, varscan2
- FAM3A | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 26/31 reads (84%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs935454242; called by muse, mutect2, varscan2
- FBN3 | c.7753C>T p.R2585C | Missense Mutation (SNP) | VAF 95/210 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.511); catalogued as rs760490060, COSV54459122; called by muse, mutect2, varscan2
- FBXO38 | c.1756C>T p.R586C | Missense Mutation (SNP) | VAF 76/160 reads (48%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.276); catalogued as rs144744644; called by muse, mutect2
- FCGRT | c.320del p.G107Efs*29 | Frame Shift Del (DEL) | VAF 19/50 reads (38%) | catalogued as rs1568698688; called by mutect2, pindel, varscan2
- FGF12 | c.355C>T p.Q119* (on ENST00000454309 / NM_021032.5; = p.Q57* on NM_004113.6) | Nonsense Mutation (SNP) | VAF 122/150 reads (81%) | catalogued as COSV53175053; called by muse, mutect2, varscan2
- FLNA | c.7834C>T p.R2612W (on ENST00000369850 / NM_001110556.2; = p.R2604W on NM_001456.3) | Missense Mutation (SNP) | VAF 160/178 reads (90%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); catalogued as rs781864075; called by muse, mutect2, varscan2
- FLRT2 | c.1595C>T p.T532M | Missense Mutation (SNP) | VAF 70/165 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.09); catalogued as rs1316261526; called by muse, varscan2
- FMO2 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 99/221 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.393); catalogued as COSV52950469; called by muse, mutect2, varscan2
- FOXRED2 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 64/150 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as rs866146880; called by muse, mutect2, varscan2
- GABRD | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 101/222 reads (45%) | SIFT tolerated (0.96); PolyPhen probably damaging (0.997); catalogued as rs1477740666, COSV66081485; called by muse, mutect2, varscan2
- GALNS | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 53/101 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1209154325, CM970577, COSV99076532; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GASK1B | c.434T>C p.L145S | Missense Mutation (SNP) | VAF 51/64 reads (80%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as COSV99647340; called by muse, mutect2, varscan2
- GDF5 | c.1165G>T p.G389C | Missense Mutation (SNP) | VAF 57/125 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65502554; called by muse, mutect2, varscan2
- GGN | c.1843C>T p.L615= | Splice Region (SNP) | VAF 39/80 reads (49%) | catalogued as rs750473087; called by muse, mutect2, varscan2
- GIGYF2 | c.541A>C p.N181H | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV65248226; called by muse, mutect2, varscan2
- GIMAP8 | c.1465G>A p.V489M | Missense Mutation (SNP) | VAF 71/176 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1202631797, COSV56230804; called by muse, mutect2, varscan2
- GLB1L2 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 73/91 reads (80%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as rs202239114, COSV60278512; called by muse, mutect2, varscan2
- GOLPH3L | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as COSV55045960; called by muse, mutect2, varscan2
- GRIK4 | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 28/36 reads (78%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as rs758251026; called by muse, mutect2, varscan2
- GRXCR2 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV65060832; called by muse, mutect2, varscan2
- GTF3C1 | c.609G>T p.K203N | Missense Mutation (SNP) | VAF 47/86 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62244308; called by muse, mutect2, varscan2
- HDAC9 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 69/148 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs369708624, COSV101286704; called by muse, mutect2, varscan2
- HERC2 | c.10628C>T p.A3543V | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs774101960, COSV55317385, COSV55325853; called by muse, mutect2, varscan2
- HHATL | c.1010+1G>A p.X337_splice | Splice Site (SNP) | VAF 81/99 reads (82%) | catalogued as rs1230839485; called by muse, mutect2, varscan2
- HMX2 | c.779C>T p.S260L | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as rs770685100; called by muse, varscan2
- HNRNPM | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV57695470; called by muse, mutect2, varscan2
- ICAM1 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99320535; called by muse, mutect2, varscan2
- IDUA | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 69/141 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751396984; called by muse, mutect2, varscan2
- INPP5D | c.2074A>G p.S692G (on ENST00000445964 / NM_001017915.3; = p.S691G on NM_005541.5) | Missense Mutation (SNP) | VAF 110/239 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as rs772915023; called by muse, mutect2, varscan2
- IRGC | c.401A>G p.Y134C | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.605); catalogued as rs754319451; called by muse, mutect2, varscan2
- ITGAX | c.566C>T p.S189F | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99192091; called by muse, mutect2, varscan2
- KALRN | c.8155dup p.M2719Nfs*27 (on ENST00000360013 / NM_001024660.4; = p.M1022Nfs*27 on NM_007064.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 38/50 reads (76%) | catalogued as rs1249367467; called by mutect2, varscan2
- KCNIP4 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.407); catalogued as rs149977507; called by muse, mutect2, varscan2
- KCNJ10 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63633950; called by muse, mutect2, varscan2
- KCNS1 | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 82/157 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60260027; called by muse, mutect2, varscan2
- KIAA1217 | c.1487del p.P496Lfs*26 | Frame Shift Del (DEL) | VAF 32/92 reads (35%) | catalogued as COSV56813511; called by mutect2, pindel, varscan2
- KLC3 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 145/296 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs369849969; called by muse, mutect2, varscan2
- KLHL22 | c.1253G>A p.R418H | Missense Mutation (SNP) | VAF 65/142 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.973); catalogued as rs1220749356, COSV61021912; called by muse, mutect2, varscan2
- KMT2D | c.16285A>G p.T5429A | Missense Mutation (SNP) | VAF 31/281 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV56454360; called by muse, mutect2, varscan2
- KRT84 | c.664C>T p.R222W | Missense Mutation (SNP) | VAF 46/87 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs370908162; called by muse, mutect2, varscan2
- L3MBTL2 | c.1496C>T p.P499L | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.901); catalogued as rs765878433, COSV53433447; called by muse, mutect2, varscan2
- LAMA4 | c.4617dup p.L1540Tfs*4 (on ENST00000230538 / NM_001105206.3; = p.L1533Tfs*4 on NM_002290.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 18/63 reads (29%) | catalogued as rs1554325717; called by pindel, varscan2
- LBP | c.1030C>T p.P344S | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.65); PolyPhen benign (0.012); catalogued as rs146665734; called by muse, mutect2, varscan2
- LNPEP | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777688166; called by muse, mutect2, varscan2
- LOXL3 | c.824del p.G275Afs*5 | Frame Shift Del (DEL) | VAF 74/160 reads (46%) | catalogued as rs746133895; called by mutect2, varscan2
- LPA | c.4193G>A p.G1398D | Missense Mutation (SNP) | VAF 124/275 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756618647; called by muse, varscan2
- LRGUK | c.671G>A p.G224D | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV99604526; called by muse, mutect2, varscan2
- LRP1 | c.6616C>T p.R2206C | Missense Mutation (SNP) | VAF 67/128 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1216130377, COSV54524960; called by muse, mutect2, varscan2
- LRP1B | c.3010C>T p.H1004Y | Missense Mutation (SNP) | VAF 82/178 reads (46%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.977); catalogued as COSV101254288, COSV67203069; called by muse, mutect2, varscan2
- LRRC34 | c.809C>T p.A270V (on ENST00000446859 / NM_001172779.2; = p.A238V on NM_153353.5) | Missense Mutation (SNP) | VAF 49/63 reads (78%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs201395437; called by muse, mutect2, varscan2
- LZTS1 | c.1084A>G p.K362E | Missense Mutation (SNP) | VAF 59/69 reads (86%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV56118657; called by muse, mutect2, varscan2
- MAN2B1 | c.1250C>A p.A417E | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs762379857; called by muse, mutect2, varscan2
- MAP1B | c.5918G>A p.S1973N | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.084); catalogued as COSV57099844; called by muse, mutect2
- MAP4K4 | c.2107C>T p.R703C (on ENST00000347699 / NM_001242559.2; = p.R618C on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/65 reads (77%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs369479508; called by muse, mutect2, varscan2
- MAPK8IP3 | c.635C>A p.P212H | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.885); catalogued as COSV51721152, COSV99167685; called by muse, mutect2, varscan2
- MAPK8IP3 | c.2126G>T p.C709F | Missense Mutation (SNP) | VAF 78/179 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99170056; called by muse, mutect2, varscan2
- MARS2 | c.1775G>A p.R592Q | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as rs377701225; ClinVar: likely benign; called by muse, mutect2, varscan2
- MASTL | c.2423C>T p.A808V (on ENST00000375940 / NM_001372029.1; = p.A807V on NM_032844.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs775469107; called by muse, mutect2, varscan2
- MEGF8 | c.497del p.G166Vfs*53 | Frame Shift Del (DEL) | VAF 44/130 reads (34%) | catalogued as rs762115034; called by mutect2, pindel, varscan2
- MGA | c.9034C>T p.P3012S (on ENST00000219905 / NM_001164273.1; = p.P2803S on NM_001080541.2) | Missense Mutation (SNP) | VAF 80/182 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54950064; called by muse, mutect2, varscan2
- MGAM | c.2161C>T p.P721S | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV72074615; called by muse, mutect2, varscan2
- MGAM | c.5509G>A p.D1837N | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs1276639282, COSV72074272, COSV72075163; called by muse, mutect2, varscan2
- MICAL1 | c.637G>A p.V213I | Missense Mutation (SNP) | VAF 68/190 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs754526970; called by muse, mutect2, varscan2
- MICAL3 | c.3533G>T p.G1178V | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1225729504; called by muse, mutect2, varscan2
- MMAB | c.539C>T p.S180L | Missense Mutation (SNP) | VAF 52/105 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs368584846, CM061123; called by muse, mutect2, varscan2
- MMEL1 | c.2297G>A p.R766Q | Missense Mutation (SNP) | VAF 69/160 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs199926063; called by muse, mutect2, varscan2
- MROH2B | c.4216A>G p.T1406A | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated (0.6); PolyPhen benign (0.229); catalogued as rs892395973; called by muse, mutect2, varscan2
- MSRB3 | c.533G>A p.G178D | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV57595651; called by muse, varscan2
- MYH6 | c.897G>C p.L299= | Splice Region (SNP) | VAF 41/94 reads (44%) | catalogued as COSV62452610; called by muse, mutect2, varscan2
- MYO15A | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 116/148 reads (78%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV52751757; called by muse, mutect2, varscan2
- MYT1L | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 54/97 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV101220777, COSV67722706; called by muse, mutect2, varscan2
- NAPEPLD | c.842del p.F281Sfs*14 | Frame Shift Del (DEL) | VAF 28/47 reads (60%) | catalogued as rs746683932, COSV100439928; called by mutect2, varscan2
- NBAS | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 57/119 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV55729931; called by muse, mutect2, varscan2
- NDRG3 | c.835C>T p.P279S (on ENST00000349004 / NM_032013.4; = p.P267S on NM_022477.4) | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1363884803; called by muse, varscan2
- NELFA | c.649C>T p.R217W (on ENST00000542778; = p.R206W on NM_005663.5) | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs145121989; called by muse, mutect2, varscan2
- NLGN2 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 63/78 reads (81%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as rs1085307473, COSV100192957; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOSTRIN | c.572del p.N191Tfs*9 (on ENST00000317647 / NM_001039724.4; = p.N113Tfs*9 on NM_052946.3) | Frame Shift Del (DEL) | VAF 108/278 reads (39%) | catalogued as rs1282346576; called by mutect2, varscan2
- NRIP1 | c.2637T>A p.D879E | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs1404608681; called by muse, mutect2, varscan2
- NTAN1 | c.824T>A p.L275* | Nonsense Mutation (SNP) | VAF 35/109 reads (32%) | catalogued as COSV55074477; called by muse, mutect2, varscan2
- OBSCN | c.9710C>T p.A3237V | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.141); catalogued as rs781114361; called by muse, mutect2
- OGFR | c.1372C>T p.R458W | Missense Mutation (SNP) | VAF 57/155 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as rs1490473697; called by muse, mutect2, varscan2
- OR10Z1 | c.265del p.D89Tfs*48 | Frame Shift Del (DEL) | VAF 50/121 reads (41%) | catalogued as rs752054889; called by mutect2, varscan2
- OR4F15 | c.428A>G p.Y143C | Missense Mutation (SNP) | VAF 118/244 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as COSV59968258; called by muse, mutect2, varscan2
- P2RY2 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 96/205 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.49); catalogued as rs751836374, COSV60776807; called by muse, mutect2, varscan2
- PAIP1 | c.267G>A p.E89= | Splice Region (SNP) | VAF 14/47 reads (30%) | catalogued as rs755434574; called by muse, mutect2
- PARD3B | c.2509dup p.T837Nfs*25 (on ENST00000406610 / NM_001302769.2; = p.T768Nfs*25 on NM_057177.7) | Frame Shift Ins (INS) | VAF 70/174 reads (40%) | catalogued as rs772816756; called by mutect2, varscan2
- PCBP3 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs1033727137; called by muse, mutect2, varscan2
- PCDH10 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 25/33 reads (76%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.001); catalogued as rs767146068; called by muse, mutect2, varscan2
- PCDHB2 | c.1171C>T p.L391F | Missense Mutation (SNP) | VAF 131/277 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV99039264; called by muse, mutect2, varscan2
- PCDHB5 | c.1378C>T p.R460* | Nonsense Mutation (SNP) | VAF 118/285 reads (41%) | catalogued as rs201677139, COSV50647416; called by mutect2, varscan2
- PCDHB7 | c.1873C>T p.R625C | Missense Mutation (SNP) | VAF 56/258 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99176706; called by muse, mutect2, varscan2
- PCDHGB6 | c.1525G>A p.A509T | Missense Mutation (SNP) | VAF 73/176 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.605); catalogued as rs1000014772, COSV53909164; called by muse, mutect2, varscan2
- PDILT | c.286A>T p.I96F | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as rs1227255869; called by muse, mutect2, varscan2
- PIK3R3 | c.1321_1323del p.N441del | In Frame Del (DEL) | VAF 65/155 reads (42%) | catalogued as rs1557544840; called by mutect2, pindel, varscan2
- PIK3R3 | c.1210T>C p.C404R | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751601128; called by muse, mutect2, varscan2
- PIK3R5 | c.2611C>T p.P871S | Missense Mutation (SNP) | VAF 41/51 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1399331507; called by muse, mutect2, varscan2
- PITX2 | c.433C>T p.R145C (on ENST00000354925 / NM_001204397.1; = p.R152C on NM_000325.6) | Missense Mutation (SNP) | VAF 60/130 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60741626; called by muse, mutect2, varscan2
- PKDREJ | c.1276G>A p.D426N | Missense Mutation (SNP) | VAF 68/130 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs770746561, COSV53553077; called by muse, mutect2, varscan2
- PKN3 | c.2036_2038del p.K679del | In Frame Del (DEL) | VAF 24/96 reads (25%) | catalogued as rs747170999; called by pindel, varscan2
- PLB1 | c.51del p.Q18Kfs*24 | Frame Shift Del (DEL) | VAF 43/109 reads (39%) | catalogued as COSV100579686; called by mutect2, pindel, varscan2
- PLEKHM3 | c.1963A>G p.K655E | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.93); catalogued as rs1291823997, COSV101216813; called by muse, mutect2, varscan2
- POFUT2 | c.988G>T p.V330L | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.019); catalogued as COSV100499466; called by muse, mutect2, varscan2
- POLK | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 71/143 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs769338634; called by muse, mutect2, varscan2
- PPM1F | c.1156G>A p.G386R | Missense Mutation (SNP) | VAF 63/149 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as rs764002847, COSV54284811; called by muse, mutect2, varscan2
- PRR12 | c.442G>A p.E148K (on ENST00000615927; = p.E969K on NM_020719.3) | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs1298843770; called by muse, mutect2, varscan2
- PRUNE2 | c.2090G>A p.R697K | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV65041746, COSV65041956; called by muse, mutect2, varscan2
- PSMB1 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs776137090; called by muse, mutect2, varscan2
- PSMB5 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT tolerated (0.31); PolyPhen benign (0.02); catalogued as rs764303754; called by muse, mutect2, varscan2
- PTCH1 | c.589T>C p.W197R | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1312950307; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPRF | c.4198G>A p.V1400I | Missense Mutation (SNP) | VAF 122/313 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs764399239, COSV63445540; called by muse, mutect2, varscan2
- PTPRT | c.3986A>C p.Y1329S | Missense Mutation (SNP) | VAF 73/155 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV99049495; called by muse, mutect2, varscan2
- QKI | c.904G>C p.E302Q | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.376); catalogued as COSV99274303, COSV99275474; called by muse, mutect2, varscan2
- RAVER1 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 136/344 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as COSV50330088; called by muse, mutect2, varscan2
- RBM27 | c.2448A>C p.K816N | Missense Mutation (SNP) | VAF 103/244 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as rs1178583149, COSV54587513; called by muse, mutect2, varscan2
- RBMS3 | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs202069394; called by muse, mutect2, varscan2
- RCCD1 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 137/290 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as rs760490428; called by muse, mutect2, varscan2
- RFTN1 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 73/91 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1360540913; called by muse, mutect2, varscan2
- RGS12 | c.3870del p.Q1292Rfs*49 | Frame Shift Del (DEL) | VAF 22/44 reads (50%) | catalogued as rs751982308; called by mutect2, varscan2
- RNF214 | c.1791C>G p.I597M | Missense Mutation (SNP) | VAF 53/73 reads (73%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.655); catalogued as rs1431408361; called by muse, mutect2, varscan2
- RNF43 | c.1352G>A p.C451Y | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT tolerated (0.85); PolyPhen benign (0.059); catalogued as rs1476396767; called by muse, mutect2, varscan2
- RNPEPL1 | c.1864C>T p.R622W | Missense Mutation (SNP) | VAF 69/175 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs193086300; called by muse, mutect2, varscan2
- RORC | c.666C>G p.S222R | Missense Mutation (SNP) | VAF 131/280 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV59095911; called by muse, mutect2, varscan2
- ROS1 | c.4417A>G p.T1473A | Missense Mutation (SNP) | VAF 75/176 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0.039); catalogued as COSV63861232; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 18/38 reads (47%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPN2 | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 77/178 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.915); catalogued as rs145802754; called by muse, varscan2
- RSPH10B | c.68_69dup p.D24Lfs*4 | Frame Shift Ins (INS) | VAF 22/105 reads (21%) | catalogued as rs1356399611; called by mutect2, varscan2
- SASS6 | c.439G>A p.V147M | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as rs751551434; called by muse, mutect2, varscan2
- SCAF4 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.009); catalogued as rs746332637, COSV54586720; called by muse, mutect2, varscan2
- SCGB2B2 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 65/142 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs757001262, COSV64857172; called by muse, mutect2, varscan2
- SCLY | c.801G>T p.K267N (on ENST00000651534; = p.K259N on NM_016510.7) | Missense Mutation (SNP) | VAF 94/243 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54543259; called by muse, varscan2
- SCN2A | c.3788C>T p.A1263V | Missense Mutation (SNP) | VAF 72/141 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1559395534; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCRN3 | c.235dup p.A79Gfs*7 | Frame Shift Ins (INS) | VAF 29/82 reads (35%) | catalogued as rs1326204105; called by mutect2, pindel, varscan2
- SDHD | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 79/105 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as CM073335, CM094770; called by muse, mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 21/64 reads (33%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEL1L2 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 65/84 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99532517; called by muse, mutect2, varscan2
- SELP | c.1168G>C p.E390Q | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.331); catalogued as rs1180129524; called by muse, mutect2, varscan2
- SEMA6D | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1335756274, COSV60377185; called by muse, mutect2, varscan2
- SGPP1 | c.356A>G p.Q119R | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.074); catalogued as COSV55976981; called by muse, varscan2
- SGTA | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as rs374479958; called by muse, mutect2, varscan2
- SHANK3 | c.4292C>T p.S1431L | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs753424909; called by muse, varscan2
- SHH | c.635C>T p.T212I | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.739); catalogued as rs766630931; called by muse, varscan2
- SHPRH | c.3155G>A p.R1052H (on ENST00000275233 / NM_001042683.3; = p.R1061H on NM_173082.3) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780409165; called by mutect2, varscan2
- SLC12A2 | c.2462G>A p.G821D | Missense Mutation (SNP) | VAF 54/109 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV52476554; called by muse, mutect2, varscan2
- SLC12A4 | c.2186C>T p.S729F | Missense Mutation (SNP) | VAF 45/58 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs1368965133; called by muse, mutect2, varscan2
- SLC24A4 | c.596C>T p.T199M | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs372741185; called by muse, mutect2, varscan2
- SLC35B2 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as rs750708037; called by muse, mutect2, varscan2
- SLC44A1 | c.1244A>G p.Y415C | Missense Mutation (SNP) | VAF 61/146 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs769514964; called by muse, mutect2, varscan2
- SLITRK3 | c.2902G>A p.E968K | Missense Mutation (SNP) | VAF 51/68 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1181746974, COSV53845770, COSV53848032, COSV53848768; called by muse, mutect2, varscan2
- SMARCA4 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs780497718; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPON2 | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763104530; called by muse, mutect2, varscan2
- SPPL2A | c.1298_1300del p.S433del | In Frame Del (DEL) | VAF 10/21 reads (48%) | catalogued as rs1342674272; called by pindel, varscan2
- SPTB | c.1294G>A p.A432T | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.746); catalogued as rs1285270460, COSV101071990; called by muse, mutect2, varscan2
- SPTBN5 | c.8371C>T p.R2791C | Missense Mutation (SNP) | VAF 56/106 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs761596222; called by muse, mutect2, varscan2
- SPTLC2 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.05); catalogued as rs752506362; called by muse, mutect2, varscan2
- SREK1IP1 | c.271del p.R91Gfs*67 | Frame Shift Del (DEL) | VAF 18/42 reads (43%) | catalogued as rs750306056; called by mutect2, varscan2
- SRMS | c.44_46del p.F15del | In Frame Del (DEL) | VAF 34/102 reads (33%) | catalogued as rs1282409629; called by pindel, varscan2
- SRRM4 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs189389386, COSV99939707; called by muse, mutect2, varscan2
- STAB1 | c.2432G>A p.S811N | Missense Mutation (SNP) | VAF 102/127 reads (80%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV58741433; called by muse, mutect2, varscan2
- STRA6 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as rs1395108307; called by muse, mutect2, varscan2
- SUOX | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 88/225 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as rs76442086; called by muse, mutect2, varscan2
- TBL2 | c.1012G>A p.A338T | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs1563446854; called by muse, mutect2, varscan2
- TBRG4 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 137/301 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs745698557; called by muse, mutect2, varscan2
- TCERG1 | c.121C>T p.R41* | Nonsense Mutation (SNP) | VAF 58/125 reads (46%) | catalogued as COSV104393328; called by muse, mutect2, varscan2
- TFPI | c.603A>C p.Q201H | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.059); catalogued as COSV99258169; called by muse, mutect2, varscan2
- TG | c.2621G>A p.G874D | Missense Mutation (SNP) | VAF 74/92 reads (80%) | SIFT tolerated (0.15); PolyPhen benign (0.092); catalogued as COSV55082765; called by muse, mutect2, varscan2
- TGFBI | c.1874T>C p.V625A | Missense Mutation (SNP) | VAF 164/416 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as CM074596; called by muse, mutect2, varscan2
- TGFBR3 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.521); catalogued as rs753625720; called by muse, mutect2, varscan2
- THBS2 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 61/166 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs144458205, COSV64682177; called by muse, mutect2, varscan2
- THSD7B | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1432017189, COSV55687904, COSV55747352; called by mutect2, varscan2
- TLE4 | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.568); catalogued as COSV99512316; called by muse, varscan2
- TM2D3 | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as rs149437101; called by muse, mutect2
- TMC3 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs1409182788; called by muse, mutect2, varscan2
- TMC7 | c.1327A>C p.T443P | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV58583805; called by muse, mutect2, varscan2
- TMED10 | c.104A>G p.H35R | Missense Mutation (SNP) | VAF 127/381 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as rs753647635; called by muse, mutect2, varscan2
- TMEM199 | c.389G>A p.G130D | Missense Mutation (SNP) | VAF 31/36 reads (86%) | SIFT tolerated (0.3); PolyPhen benign (0.061); catalogued as COSV99134677; called by muse, mutect2, varscan2
- TMEM201 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 104/275 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0.01); catalogued as rs752313181, COSV61051216, COSV61052237; called by muse, mutect2, varscan2
- TMEM215 | c.208C>A p.P70T | Missense Mutation (SNP) | VAF 66/137 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61363545; called by muse, mutect2, varscan2
- TMEM60 | c.231del p.A78Pfs*11 | Frame Shift Del (DEL) | VAF 38/86 reads (44%) | catalogued as rs749773249; called by mutect2, varscan2
- TNXB | c.11537C>T p.A3846V (on ENST00000647633; = p.A3599V on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/417 reads (21%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.664); catalogued as rs776166336; called by muse, mutect2, varscan2
- TRIM59 | c.604del p.S202Vfs*3 | Frame Shift Del (DEL) | VAF 26/35 reads (74%) | catalogued as rs763112993; called by mutect2, varscan2
- TRMT1 | c.1669G>A p.A557T | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.23); catalogued as COSV53400913; called by muse, mutect2, varscan2
- TRPA1 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 77/90 reads (86%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as rs567896348; called by muse, mutect2, varscan2
- TRPV2 | c.2047C>T p.R683W | Missense Mutation (SNP) | VAF 62/79 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs554857511; called by muse, mutect2, varscan2
- TTC31 | c.1339G>A p.A447T | Missense Mutation (SNP) | VAF 74/169 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs773459318; called by muse, mutect2, varscan2
- TTN | c.62035C>T p.R20679C (on ENST00000591111; = p.R13255C on NM_003319.4) | Missense Mutation (SNP) | VAF 56/132 reads (42%) | PolyPhen possibly damaging (0.648); catalogued as rs772361876, COSV59865594, COSV60239584; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBA8 | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.094); catalogued as rs940095586, COSV100283046; called by muse, mutect2
- TYW1 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs201171310, COSV62755749, COSV62756396; called by muse, mutect2, varscan2
- UBA6 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 59/154 reads (38%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1213127161; called by muse, mutect2, varscan2
- UBE4B | c.1825G>A p.E609K (on ENST00000343090 / NM_001105562.3; = p.E480K on NM_006048.5) | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.652); catalogued as COSV53536531; called by muse, mutect2, varscan2
- UCN3 | c.93del p.I32Sfs*23 | Frame Shift Del (DEL) | VAF 41/103 reads (40%) | catalogued as COSV66824074; called by mutect2, pindel, varscan2
- UNC13D | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 54/66 reads (82%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs1167822487; called by muse, mutect2, varscan2
- UNC79 | c.625T>C p.S209P (on ENST00000393151 / NM_001346218.2; = p.S32P on NM_020818.5) | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.663); catalogued as rs1252000710; called by muse, mutect2, varscan2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 24/32 reads (75%) | catalogued as rs767420916; called by mutect2, varscan2
- USP15 | c.1483G>A p.V495I (on ENST00000280377 / NM_001351159.2; = p.V466I on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.019); catalogued as COSV54787380; called by muse, mutect2, varscan2
- USP21 | c.512G>A p.S171N | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs752768895; called by muse, mutect2, varscan2
- USP7 | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.056); catalogued as rs1352445138; called by muse, varscan2
- UTRN | c.10088A>G p.N3363S | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.503); catalogued as rs775875409; called by muse, mutect2, varscan2
- VASH2 | c.242T>C p.V81A | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as rs756578657; called by muse, mutect2, varscan2
- VAV3 | c.1157T>G p.L386R | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV100580155; called by muse, mutect2, varscan2
- WARS2 | c.10C>T p.H4Y | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs758600141; called by muse, mutect2, varscan2
- WASHC5 | c.2087G>T p.G696V | Missense Mutation (SNP) | VAF 34/43 reads (79%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as CM138345; called by muse, mutect2, varscan2
- YBX3 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 58/85 reads (68%) | SIFT tolerated (0.05); PolyPhen benign (0.334); catalogued as COSV54386755; called by muse, mutect2, varscan2
- ZAP70 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 58/111 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as rs1047650227; called by muse, mutect2, varscan2
- ZC3H18 | c.2037del p.R680Gfs*5 | Frame Shift Del (DEL) | VAF 42/98 reads (43%) | catalogued as rs751577786; called by mutect2, varscan2
- ZFAT | c.739T>C p.Y247H | Missense Mutation (SNP) | VAF 88/106 reads (83%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs773246438; called by muse, mutect2, varscan2
- ZFR | c.3157G>A p.D1053N | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.956); catalogued as rs55686708; called by muse, mutect2, varscan2
- ZNF292 | c.4427C>T p.T1476I | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as rs749237267; called by muse, mutect2, varscan2
- ZNF331 | c.1064A>G p.Y355C | Missense Mutation (SNP) | VAF 105/249 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs759573823; called by muse, mutect2, varscan2
- ZNF335 | c.2411C>T p.A804V | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV100532930; called by muse, mutect2, varscan2
- ZNF365 | c.1196del p.K399Sfs*6 | Frame Shift Del (DEL) | VAF 42/90 reads (47%) | catalogued as rs751774089; called by mutect2, varscan2
- ZNF454 | c.946A>G p.T316A | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.072); catalogued as rs1165172723; called by muse, mutect2, varscan2
- ZNF559 | c.1349C>T p.S450L | Missense Mutation (SNP) | VAF 76/182 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.337); catalogued as rs377766347; called by muse, mutect2, varscan2
- ZNF563 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 69/199 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as rs757126632; called by muse, mutect2, varscan2
- ZNF598 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as rs1224821654; called by muse, varscan2
- ZNF608 | c.4418C>T p.P1473L | Missense Mutation (SNP) | VAF 59/126 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs755610596; called by muse, mutect2, varscan2
- ZNF668 | c.1751C>G p.A584G | Missense Mutation (SNP) | VAF 56/137 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.608); catalogued as COSV100336880, COSV56217188; called by muse, mutect2, varscan2
- ZNF804B | c.817A>G p.T273A | Missense Mutation (SNP) | VAF 61/122 reads (50%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV100301307; called by muse, mutect2, varscan2
- ZSWIM8 | c.5085del p.Y1696Tfs*17 (on ENST00000605216 / NM_001242487.2; = p.Y1701Tfs*17 on NM_015037.3) | Frame Shift Del (DEL) | VAF 62/158 reads (39%) | catalogued as rs769663113; called by mutect2, varscan2
- A4GALT | c.201del p.T68Pfs*46 | Frame Shift Del (DEL) | VAF 14/26 reads (54%) | called by mutect2, varscan2
- AACS | c.103G>C p.A35P | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- ABHD6 | c.335C>T p.T112I | Missense Mutation (SNP) | VAF 126/158 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- ABI3BP | c.1979G>A p.R660K | Missense Mutation (SNP) | VAF 35/37 reads (95%) | SIFT tolerated (0.6); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ABITRAM | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 172/411 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- AC008397.2 | c.745T>A p.S249T | Missense Mutation (SNP) | VAF 71/196 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- ACAD10 | c.1532T>C p.V511A | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ACBD4 | c.498C>G p.S166R | Missense Mutation (SNP) | VAF 42/51 reads (82%) | SIFT deleterious (0.04); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- ACOT4 | c.721A>C p.M241L | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ADAMTS10 | c.3305G>A p.G1102D | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS12 | c.208G>A p.G70S | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.5); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ADAMTS17 | c.3214T>A p.W1072R | Missense Mutation (SNP) | VAF 74/164 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS17 | c.2947A>G p.T983A | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, varscan2
- ADCYAP1R1 | c.190T>G p.W64G | Missense Mutation (SNP) | VAF 113/304 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRE2 | c.1528A>G p.T510A | Missense Mutation (SNP) | VAF 92/221 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADGRF4 | c.521dup p.L174Ffs*3 | Frame Shift Ins (INS) | VAF 19/80 reads (24%) | called by mutect2, pindel, varscan2
- ADH7 | c.229A>T p.I77F | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- ADNP | c.2864G>C p.S955T | Missense Mutation (SNP) | VAF 88/234 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- ADRA2A | c.739A>G p.S247G | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AFTPH | c.1495G>T p.D499Y | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- AGA | c.559A>G p.I187V | Missense Mutation (SNP) | VAF 79/99 reads (80%) | SIFT tolerated (0.81); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AGBL1 | c.1799T>C p.F600S | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGBL2 | c.2016+1G>A p.X672_splice | Splice Site (SNP) | VAF 21/29 reads (72%) | called by muse, mutect2, varscan2
- AGO3 | c.354T>A p.D118E | Missense Mutation (SNP) | VAF 103/249 reads (41%) | SIFT tolerated (0.93); PolyPhen benign (0.007); called by muse, varscan2
- AGPS | c.344G>T p.G115V | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AHNAK2 | c.5731A>G p.M1911V | Missense Mutation (SNP) | VAF 109/251 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- AKAP12 | c.2524G>T p.D842Y | Missense Mutation (SNP) | VAF 119/291 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- AL162417.1 | c.67C>A p.L23M | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ALDH18A1 | c.559-1G>C p.X187_splice | Splice Site (SNP) | VAF 58/119 reads (49%) | called by muse, mutect2, varscan2
- ALG3 | c.661C>T p.L221F | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); called by muse, varscan2
- ALOX5 | c.1628T>A p.V543E | Missense Mutation (SNP) | VAF 74/127 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ALOXE3 | c.1014C>A p.C338* | Nonsense Mutation (SNP) | VAF 44/56 reads (79%) | called by muse, varscan2
- ALS2 | c.1528A>T p.T510S | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- AMER3 | c.1897C>A p.P633T | Missense Mutation (SNP) | VAF 71/153 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ANKRD2 | c.361A>T p.K121* | Nonsense Mutation (SNP) | VAF 54/130 reads (42%) | called by muse, varscan2
- ANKRD26 | c.3271A>G p.T1091A | Missense Mutation (SNP) | VAF 52/100 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- ANKRD30A | c.1782A>G p.I594M (on ENST00000611781; = p.I538M on NM_052997.2) | Missense Mutation (SNP) | VAF 54/346 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.075); called by muse, varscan2
- ANKRD30A | c.2496A>G p.I832M (on ENST00000611781; = p.I776M on NM_052997.2) | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- ANKRD45 | c.394C>G p.L132V | Missense Mutation (SNP) | VAF 51/128 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- ANKRD52 | c.2449_2450insG p.S817Cfs*17 | Frame Shift Ins (INS) | VAF 58/194 reads (30%) | called by pindel, varscan2
- ANLN | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANXA11 | c.575G>T p.G192V | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- APAF1 | c.1393C>T p.Q465* (on ENST00000551964 / NM_181861.2; = p.Q454* on NM_001160.3) | Nonsense Mutation (SNP) | VAF 41/80 reads (51%) | called by muse, mutect2, varscan2
- APBA2 | c.2209T>C p.F737L | Missense Mutation (SNP) | VAF 105/229 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- APC | c.7628G>A p.R2543K | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- APOB | c.6494T>A p.I2165N | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- APOL6 | c.514T>A p.Y172N | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- ARHGEF11 | c.200T>A p.V67D | Missense Mutation (SNP) | VAF 86/214 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ARMC5 | c.377G>T p.R126L | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- ASPDH | c.497C>T p.A166V (on ENST00000389208 / NM_001114598.2; = p.A61V on NM_001024656.3) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASZ1 | c.238T>C p.W80R | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ATG4D | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- ATP2A1 | c.2237C>T p.A746V | Missense Mutation (SNP) | VAF 106/262 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, varscan2
- ATP2C1 | c.2728A>C p.S910R | Missense Mutation (SNP) | VAF 55/75 reads (73%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP6V0C | c.5C>G p.S2C | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.237); called by muse, varscan2
- ATRN | c.1834G>T p.V612F | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- ATXN7L3 | c.175A>C p.K59Q | Missense Mutation (SNP) | VAF 70/94 reads (74%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- AVPR1A | c.580G>A p.V194M | Missense Mutation (SNP) | VAF 94/220 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, varscan2
- AXL | c.1892T>C p.F631S (on ENST00000301178 / NM_021913.5; = p.F622S on NM_001699.6) | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- BAP1 | c.1596dup p.G533Wfs*4 | Frame Shift Ins (INS) | VAF 78/127 reads (61%) | called by mutect2, pindel, varscan2
- BAZ2A | c.4307G>A p.C1436Y | Missense Mutation (SNP) | VAF 89/195 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- BCL11B | c.547del p.L183Cfs*98 | Frame Shift Del (DEL) | VAF 47/173 reads (27%) | called by mutect2, pindel, varscan2
- BCL2L2 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- BEST1 | c.440T>A p.V147D | Missense Mutation (SNP) | VAF 87/128 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BICRAL | c.1261A>G p.N421D | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- BMP6 | c.1414T>C p.Y472H | Missense Mutation (SNP) | VAF 101/262 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- BMPR1A | c.1407T>A p.D469E | Missense Mutation (SNP) | VAF 96/220 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- BORCS5 | c.30G>C p.E10D | Missense Mutation (SNP) | VAF 95/144 reads (66%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C11orf54 | c.362A>G p.H121R | Missense Mutation (SNP) | VAF 51/70 reads (73%) | SIFT tolerated (0.56); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- C1orf174 | c.146A>C p.K49T | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- C2orf69 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 68/148 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, varscan2
- C9orf131 | c.1894C>A p.Q632K | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- C9orf24 | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 69/131 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CABCOCO1 | c.22T>C p.Y8H | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CABS1 | c.618G>T p.Q206H | Missense Mutation (SNP) | VAF 83/178 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CACNG7 | c.665G>A p.S222N | Missense Mutation (SNP) | VAF 125/293 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- CAD | c.2768del p.G923Afs*14 | Frame Shift Del (DEL) | VAF 103/298 reads (35%) | called by mutect2, pindel, varscan2
- CAPN2 | c.1515G>C p.K505N | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- CARD8 | c.539A>T p.Y180F (on ENST00000651546 / NM_001184900.3; = p.Y130F on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CARD8 | c.538T>A p.Y180N (on ENST00000651546 / NM_001184900.3; = p.Y130N on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- CASZ1 | c.4492T>A p.S1498T | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT tolerated (0.63); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CCDC116 | c.457A>T p.S153C | Missense Mutation (SNP) | VAF 56/118 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC142 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 68/150 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC183 | c.992A>G p.N331S | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- CCDC186 | c.1912-1G>T p.X638_splice | Splice Site (SNP) | VAF 40/88 reads (45%) | called by muse, mutect2, varscan2
- CCDC27 | c.474G>T p.E158D | Missense Mutation (SNP) | VAF 75/179 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCHCR1 | c.1682C>T p.S561F | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- CCN5 | c.103C>A p.P35T | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT tolerated (0.71); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CCNF | c.347-2A>T p.X116_splice | Splice Site (SNP) | VAF 24/59 reads (41%) | called by muse, mutect2, varscan2
- CCNF | c.448T>C p.W150R | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCR6 | c.206T>A p.I69N | Missense Mutation (SNP) | VAF 72/186 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); called by muse, varscan2
- CCR6 | c.289C>G p.L97V | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.241); called by muse, varscan2
- CCT8L2 | c.137T>C p.V46A | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- CCZ1B | c.770T>C p.I257T | Missense Mutation (SNP) | VAF 75/169 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, varscan2
- CD5L | c.491A>G p.Q164R | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- CD93 | c.1312del p.L438Sfs*150 | Frame Shift Del (DEL) | VAF 38/64 reads (59%) | called by mutect2, pindel, varscan2
- CDCA2 | c.2317G>A p.A773T | Missense Mutation (SNP) | VAF 36/40 reads (90%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEACAM5 | c.1886T>C p.I629T | Missense Mutation (SNP) | VAF 141/294 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- CELSR2 | c.391C>G p.L131V | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- CEMP1 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CENPC | c.919G>T p.E307* | Nonsense Mutation (SNP) | VAF 24/64 reads (38%) | called by muse, mutect2, varscan2
- CENPE | c.4592A>G p.K1531R | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- CENPW | c.146T>G p.L49R | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEP43 | c.213T>C p.G71= | Splice Region (SNP) | VAF 20/47 reads (43%) | called by muse, mutect2, varscan2
- CETN3 | c.153+1G>A p.X51_splice | Splice Site (SNP) | VAF 33/82 reads (40%) | called by muse, mutect2, varscan2
- CFAP65 | c.911dup p.V305Gfs*91 | Frame Shift Ins (INS) | VAF 70/215 reads (33%) | called by pindel, varscan2
- CHAF1A | c.1319C>T p.A440V | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CHST11 | c.362G>A p.C121Y | Missense Mutation (SNP) | VAF 94/229 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CILP | c.2993A>C p.Q998P | Missense Mutation (SNP) | VAF 69/176 reads (39%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- CINP | c.329A>T p.E110V | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- CLPP | c.21dup p.G8Rfs*67 | Frame Shift Ins (INS) | VAF 13/39 reads (33%) | called by pindel, varscan2
- CNNM2 | c.1531del p.L511* | Frame Shift Del (DEL) | VAF 82/170 reads (48%) | called by mutect2, varscan2
- COL4A6 | c.21G>A p.W7* | Nonsense Mutation (SNP) | VAF 161/186 reads (87%) | called by mutect2, varscan2
- COPS8 | c.399dup p.A134Cfs*23 | Frame Shift Ins (INS) | VAF 42/100 reads (42%) | called by mutect2, varscan2
- COX7A1 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- CPXCR1 | c.521A>G p.K174R | Missense Mutation (SNP) | VAF 72/86 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CRAMP1 | c.688G>C p.D230H | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- CRB2 | c.1123G>A p.D375N | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- CRYBB3 | c.413G>A p.S138N | Missense Mutation (SNP) | VAF 115/252 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- CS | c.432G>C p.R144S | Missense Mutation (SNP) | VAF 86/209 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- CUBN | c.8896C>A p.H2966N | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- CUBN | c.4541T>C p.F1514S | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- CUBN | c.1937A>T p.D646V | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- CUBN | c.1280T>C p.V427A | Missense Mutation (SNP) | VAF 108/259 reads (42%) | SIFT tolerated (0.67); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- DCAF12L2 | c.1339G>T p.G447W | Missense Mutation (SNP) | VAF 130/154 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- DENND2A | c.2096T>A p.M699K | Missense Mutation (SNP) | VAF 68/169 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DENND6A | c.1465A>T p.T489S | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT tolerated (0.48); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DHRS9 | c.698A>G p.D233G | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- DHX34 | c.2047C>T p.L683F | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- DIRAS3 | c.143T>C p.V48A | Missense Mutation (SNP) | VAF 76/188 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- DLG5 | c.2841G>A p.W947* | Nonsense Mutation (SNP) | VAF 26/61 reads (43%) | called by muse, mutect2, varscan2
- DLGAP4 | c.2364_2365insTAC p.S788_S789insY (on ENST00000339266 / NM_001365621.1; = p.S785_S786insY on NM_014902.6) | In Frame Ins (INS) | VAF 36/198 reads (18%) | called by mutect2, pindel, varscan2
- DNAH7 | c.1937C>A p.S646Y | Missense Mutation (SNP) | VAF 70/161 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- DNAJC13 | c.1597G>A p.D533N | Missense Mutation (SNP) | VAF 72/90 reads (80%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DOCK6 | c.4042C>A p.P1348T | Missense Mutation (SNP) | VAF 62/139 reads (45%) | SIFT tolerated (0.69); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DPP10 | c.209C>A p.S70Y | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- DST | c.18285A>G p.I6095M (on ENST00000361203 / NM_001374722.1; = p.I3792M on NM_015548.5) | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- DTWD1 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DUSP7 | c.1050G>A p.M350I | Missense Mutation (SNP) | VAF 68/88 reads (77%) | SIFT tolerated (0.07); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DUSP7 | c.665dup p.D222Efs*79 | Frame Shift Ins (INS) | VAF 89/123 reads (72%) | called by mutect2, varscan2
- DVL1 | c.888G>T p.E296D | Missense Mutation (SNP) | VAF 57/125 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DYNC1H1 | c.6058C>T p.P2020S | Missense Mutation (SNP) | VAF 71/157 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DYNC1H1 | c.13826T>A p.V4609D | Missense Mutation (SNP) | VAF 60/126 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DYRK2 | c.487T>A p.Y163N (on ENST00000344096 / NM_006482.3; = p.Y90N on NM_003583.4) | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- ECPAS | c.3510G>A p.W1170* | Nonsense Mutation (SNP) | VAF 43/108 reads (40%) | called by muse, mutect2, varscan2
- EEF2 | c.1687G>A p.E563K | Missense Mutation (SNP) | VAF 55/120 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- EHMT1 | c.1921A>G p.T641A | Missense Mutation (SNP) | VAF 97/222 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EIF2AK4 | c.4892dup p.V1632Gfs*10 | Frame Shift Ins (INS) | VAF 36/106 reads (34%) | called by mutect2, varscan2
- EIF2D | c.1441C>T p.P481S | Missense Mutation (SNP) | VAF 61/128 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- ELAPOR2 | c.2449T>C p.F817L (on ENST00000450689 / NM_001142749.3; = p.F650L on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- ELOVL5 | c.380C>A p.T127N | Missense Mutation (SNP) | VAF 68/195 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EMP1 | c.379C>T p.Q127* | Nonsense Mutation (SNP) | VAF 77/97 reads (79%) | called by muse, mutect2, varscan2
- EPHB4 | c.1294G>T p.E432* | Nonsense Mutation (SNP) | VAF 52/133 reads (39%) | called by muse, mutect2, varscan2
- ERAP1 | c.2381C>G p.S794C | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- ERN2 | c.1942C>T p.P648S | Missense Mutation (SNP) | VAF 52/104 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- ERRFI1 | c.380C>G p.T127S | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT tolerated (0.57); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ESPL1 | c.2375C>T p.A792V | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- EXOC6B | c.935A>T p.E312V | Missense Mutation (SNP) | VAF 42/78 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, varscan2
- EXOC8 | c.2101G>A p.A701T | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- F11R | c.815+1G>A p.X272_splice | Splice Site (SNP) | VAF 64/177 reads (36%) | called by muse, mutect2, varscan2
- FAM135A | c.31T>A p.S11T | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- FAM13A | c.1639C>T p.Q547* | Nonsense Mutation (SNP) | VAF 52/130 reads (40%) | called by muse, mutect2, varscan2
- FAM161A | c.845T>C p.F282S | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM200A | c.1192_1193del p.M398Vfs*14 | Frame Shift Del (DEL) | VAF 32/109 reads (29%) | called by pindel, varscan2
- FAM241B | c.41A>T p.D14V | Missense Mutation (SNP) | VAF 97/232 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FAM83C | c.2164C>A p.L722M | Missense Mutation (SNP) | VAF 19/179 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FAR2 | c.317A>G p.N106S | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- FARP1 | c.3137G>C p.*1046Sext*22 | Nonstop Mutation (SNP) | VAF 105/136 reads (77%) | called by muse, mutect2, varscan2
- FARS2 | c.491T>C p.L164P | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FAT1 | c.9725A>G p.D3242G | Missense Mutation (SNP) | VAF 157/196 reads (80%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAT4 | c.11093A>G p.N3698S | Missense Mutation (SNP) | VAF 76/93 reads (82%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBN1 | c.4295A>G p.D1432G | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FBN1 | c.2402A>T p.D801V | Missense Mutation (SNP) | VAF 85/201 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- FBXL22 | c.434C>T p.S145L | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- FGF21 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 58/156 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FGF23 | c.665A>G p.D222G | Missense Mutation (SNP) | VAF 62/77 reads (81%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- FGFR2 | c.445A>G p.N149D | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- FLAD1 | c.1344T>A p.F448L | Missense Mutation (SNP) | VAF 57/141 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FMN2 | c.467del p.G156Afs*296 | Frame Shift Del (DEL) | VAF 58/149 reads (39%) | called by mutect2, pindel, varscan2
- FOXD4L4 | c.56A>G p.D19G | Missense Mutation (SNP) | VAF 92/588 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FOXH1 | c.770G>A p.G257D | Missense Mutation (SNP) | VAF 32/36 reads (89%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FRAS1 | c.2316G>C p.L772F | Missense Mutation (SNP) | VAF 131/326 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.418); called by muse, mutect2
- FRMD3 | c.750T>A p.N250K | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FRMD6 | c.970T>C p.Y324H (on ENST00000344768 / NM_001267046.2; = p.Y316H on NM_152330.4) | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT tolerated (0.53); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- FRMPD1 | c.3254A>G p.D1085G | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FRMPD4 | c.1474A>G p.I492V | Missense Mutation (SNP) | VAF 43/49 reads (88%) | SIFT tolerated (0.05); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- FUT6 | c.929A>G p.K310R | Missense Mutation (SNP) | VAF 290/1038 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.05); called by muse, mutect2
- FZD8 | c.845G>A p.G282D | Missense Mutation (SNP) | VAF 82/164 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- GAB4 | c.278C>A p.T93N | Missense Mutation (SNP) | VAF 74/173 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.427); called by muse, mutect2, varscan2
- GABPB2 | c.363G>T p.E121D | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- GALNT10 | c.915del p.A306Lfs*11 | Frame Shift Del (DEL) | VAF 53/130 reads (41%) | called by mutect2, pindel, varscan2
- GALR3 | c.797G>A p.S266N | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GLB1L3 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 44/55 reads (80%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GMIP | c.2374G>A p.D792N | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.49); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- GMIP | c.1065G>C p.E355D | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GNAS | c.1217C>A p.A406E | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- GNAT2 | c.532A>G p.R178G | Missense Mutation (SNP) | VAF 94/256 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- GNPAT | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- GPR108 | c.1361A>G p.Y454C (on ENST00000264080 / NM_001080452.1; = p.Y212C on NM_020171.2) | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR3 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- GPR61 | c.223A>G p.K75E | Missense Mutation (SNP) | VAF 15/218 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- GPR83 | c.293A>G p.K98R | Missense Mutation (SNP) | VAF 83/102 reads (81%) | SIFT deleterious (0.02); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- GRHL3 | c.730A>G p.K244E (on ENST00000350501 / NM_198174.3; = p.K249E on NM_021180.3) | Missense Mutation (SNP) | VAF 75/184 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GRID2 | c.2239G>A p.E747K | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- GRIP1 | c.2043del p.G684Afs*14 (on ENST00000359742 / NM_001379345.1; = p.G632Afs*14 on NM_021150.4 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 24/73 reads (33%) | called by mutect2, pindel, varscan2
- GSDME | c.1472T>G p.L491* | Nonsense Mutation (SNP) | VAF 85/213 reads (40%) | called by muse, mutect2, varscan2
- GSN | c.213G>A p.W71* | Nonsense Mutation (SNP) | VAF 125/271 reads (46%) | called by muse, mutect2, varscan2
- GSTA2 | c.562dup p.I188Nfs*3 | Frame Shift Ins (INS) | VAF 30/75 reads (40%) | called by mutect2, pindel, varscan2
- GTPBP2 | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GUCY2D | c.3165G>C p.W1055C | Missense Mutation (SNP) | VAF 40/60 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HAUS4 | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HAUS8 | c.330A>T p.K110N | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- HCRTR1 | c.101A>G p.Y34C | Missense Mutation (SNP) | VAF 62/123 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- HDAC4 | c.536T>A p.V179D | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- HECA | c.974G>A p.S325N | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- HENMT1 | c.383T>C p.I128T | Missense Mutation (SNP) | VAF 88/192 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- HERC1 | c.13279A>G p.S4427G | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- HERC2 | c.7888T>C p.Y2630H | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- HEY2 | c.542A>G p.H181R | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- HFM1 | c.2359T>C p.Y787H | Missense Mutation (SNP) | VAF 78/167 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HHIP | c.1282G>A p.G428R | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- HIRA | c.1306del p.E436Rfs*11 | Frame Shift Del (DEL) | VAF 50/142 reads (35%) | called by mutect2, pindel, varscan2
- HIVEP2 | c.6823C>A p.P2275T | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- HK2 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT tolerated (0.46); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- HMGCLL1 | c.985A>T p.M329L | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- HMGN3 | c.124A>T p.K42* | Nonsense Mutation (SNP) | VAF 35/81 reads (43%) | called by muse, mutect2, varscan2
- HNRNPA3 | c.1064G>A p.S355N | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- HSD17B6 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 96/202 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- HSPA2 | c.1574C>T p.A525V | Missense Mutation (SNP) | VAF 59/137 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- HTT | c.2681C>T p.A894V | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HTT | c.9191C>T p.S3064F | Missense Mutation (SNP) | VAF 54/118 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- IGFBP7 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- IGLV1-50 | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 92/219 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- IGSF9 | c.2568del p.T858Lfs*70 (on ENST00000368094 / NM_001135050.2; = p.T842Lfs*70 on NM_020789.4) | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | called by mutect2, pindel, varscan2
- IL25 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 83/190 reads (44%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.492); called by muse, mutect2
- IL37 | c.110G>A p.G37D | Missense Mutation (SNP) | VAF 89/124 reads (72%) | SIFT tolerated (0.4); PolyPhen benign (0.013); called by muse, mutect2
- IMMT | c.1710G>A p.W570* | Nonsense Mutation (SNP) | VAF 28/60 reads (47%) | called by muse, mutect2, varscan2
- INF2 | c.769del p.E257Rfs*12 | Frame Shift Del (DEL) | VAF 91/250 reads (36%) | called by mutect2, pindel, varscan2
- INTS11 | c.1612C>A p.L538M | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- IQGAP2 | c.1185A>C p.R395S | Missense Mutation (SNP) | VAF 75/158 reads (47%) | SIFT tolerated (0.85); PolyPhen benign (0.003); called by muse, varscan2
- IRF5 | c.218A>T p.K73I | Missense Mutation (SNP) | VAF 58/126 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IRGQ | c.1856del p.P619Lfs*17 | Frame Shift Del (DEL) | VAF 104/249 reads (42%) | called by mutect2, pindel, varscan2
- ITIH2 | c.2583C>T p.G861= | Splice Region (SNP) | VAF 95/211 reads (45%) | called by muse, mutect2, varscan2
- ITM2A | c.562T>A p.Y188N | Missense Mutation (SNP) | VAF 126/150 reads (84%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- ITPR3 | c.6850A>T p.I2284F | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- JAK3 | c.466C>T p.L156F | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- KCNB2 | c.1057G>A p.V353I | Missense Mutation (SNP) | VAF 65/90 reads (72%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- KDM2B | c.3992T>C p.L1331P | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- KDM3A | c.2946T>A p.H982Q | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- KHDC4 | c.1574C>T p.A525V | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- KIAA1143 | c.26A>G p.Y9C | Missense Mutation (SNP) | VAF 78/97 reads (80%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- KIAA1614 | c.1943G>A p.R648Q | Missense Mutation (SNP) | VAF 66/149 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIAA2013 | c.1651A>G p.I551V | Missense Mutation (SNP) | VAF 199/600 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- KIF21B | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 66/141 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- KIFC1 | c.1174G>A p.A392T | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- KIRREL1 | c.2035A>G p.T679A | Missense Mutation (SNP) | VAF 90/221 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLHL18 | c.1117A>G p.R373G | Missense Mutation (SNP) | VAF 122/160 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- KLRK1 | c.170G>A p.C57Y | Missense Mutation (SNP) | VAF 37/45 reads (82%) | SIFT tolerated (0.58); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KMT2B | c.588_590del p.L197del | In Frame Del (DEL) | VAF 35/103 reads (34%) | called by mutect2, pindel, varscan2
- KMT2B | c.6324C>A p.D2108E | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- KMT5B | c.862A>T p.T288S | Missense Mutation (SNP) | VAF 41/57 reads (72%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- KRTAP10-2 | c.282del p.C95Afs*251 | Frame Shift Del (DEL) | VAF 60/202 reads (30%) | called by pindel, varscan2
- KRTAP10-4 | c.842G>A p.C281Y | Missense Mutation (SNP) | VAF 97/210 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- KRTAP10-9 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 149/310 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.049); called by muse, varscan2
- L34079.1 | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT deleterious, low confidence (0.02); called by muse, mutect2, varscan2
- LAMA2 | c.112G>C p.G38R | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAMA5 | c.9200del p.G3067Afs*40 | Frame Shift Del (DEL) | VAF 70/238 reads (29%) | called by mutect2, pindel, varscan2
- LARP1 | c.894_899delinsGTGG p.V299Wfs*22 (on ENST00000518297 / NM_033551.3; = p.V222Wfs*22 on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 33/127 reads (26%) | called by pindel, varscan2*
- LARP4 | c.1787C>T p.A596V | Missense Mutation (SNP) | VAF 75/185 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- LARS1 | c.1590-3dup | Splice Region (INS) | VAF 55/146 reads (38%) | called by mutect2, pindel, varscan2
- LDB3 | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LGI4 | c.103A>T p.K35* | Nonsense Mutation (SNP) | VAF 76/171 reads (44%) | called by muse, mutect2, varscan2
- LONRF1 | c.2216T>C p.V739A | Missense Mutation (SNP) | VAF 34/47 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- LRIG2 | c.3097C>T p.P1033S | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- LRP1 | c.2876A>G p.D959G | Missense Mutation (SNP) | VAF 64/145 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC42 | c.555dup p.G186Wfs*3 | Frame Shift Ins (INS) | VAF 44/165 reads (27%) | called by mutect2, pindel, varscan2
- LRRC61 | c.244G>A p.V82I | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- LRRFIP1 | c.2078_2080del p.G693del (on ENST00000392000 / NM_001137552.2; = p.G669del on NM_004735.4) | In Frame Del (DEL) | VAF 64/192 reads (33%) | called by pindel, varscan2
- LRRN3 | c.1634C>T p.S545F | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- LSAMP | c.920G>A p.R307K | Missense Mutation (SNP) | VAF 95/116 reads (82%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- LVRN | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 79/171 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, varscan2
- MACC1 | c.2360C>A p.P787H | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- MAGEC3 | c.104T>C p.V35A | Missense Mutation (SNP) | VAF 142/162 reads (88%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- MAGI3 | c.2098C>G p.P700A | Missense Mutation (SNP) | VAF 85/191 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- MAML3 | c.791A>T p.D264V | Missense Mutation (SNP) | VAF 41/67 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- MANSC1 | c.965T>G p.F322C | Missense Mutation (SNP) | VAF 64/80 reads (80%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.819); called by muse, mutect2
- MAP4K3 | c.2243dup p.N749Qfs*7 | Frame Shift Ins (INS) | VAF 38/90 reads (42%) | called by mutect2, varscan2
- MAPK1 | c.536A>G p.D179G | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.653); called by muse, varscan2
- MAPK11 | c.452T>C p.L151P | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAPKAP1 | c.755A>T p.E252V | Missense Mutation (SNP) | VAF 70/145 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); called by muse, varscan2
- MARCHF8 | c.37T>C p.S13P | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- MARF1 | c.1337T>C p.V446A | Missense Mutation (SNP) | VAF 58/127 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MCTP2 | c.2406G>T p.L802F | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- MDN1 | c.13972A>G p.K4658E | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- MEGF8 | c.4837C>A p.Q1613K (on ENST00000251268 / NM_001271938.2; = p.Q1546K on NM_001410.3) | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.89); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MEI1 | c.297dup p.G100Wfs*17 | Frame Shift Ins (INS) | VAF 38/107 reads (36%) | called by mutect2, pindel, varscan2
- METTL25 | c.281T>C p.I94T | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- MEX3C | c.1896T>G p.C632W | Missense Mutation (SNP) | VAF 90/119 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MEX3C | c.1895G>T p.C632F | Missense Mutation (SNP) | VAF 91/120 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MKX | c.1006T>G p.S336A | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MLLT1 | c.1642C>T p.R548C | Missense Mutation (SNP) | VAF 98/196 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MOXD1 | c.970A>T p.R324W | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MPHOSPH9 | c.2120A>G p.D707G | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MPP4 | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 219/493 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- MROH8 | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MSLN | c.1475dup p.Q493Pfs*54 (on ENST00000382862 / NM_013404.4; = p.Q485Pfs*54 on NM_005823.6) | Frame Shift Ins (INS) | VAF 104/219 reads (47%) | called by mutect2, varscan2
- MTHFD2L | c.392C>G p.T131S (on ENST00000395759 / NM_001144978.2; = p.T73S on NM_001004346.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/151 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- MUC16 | c.37525A>G p.T12509A | Missense Mutation (SNP) | VAF 136/322 reads (42%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); called by muse, mutect2
- MUC16 | c.6853A>G p.T2285A | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH6 | c.2356A>G p.I786V | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- MYH7 | c.2266T>A p.Y756N | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO10 | c.2151G>A p.W717* | Nonsense Mutation (SNP) | VAF 46/127 reads (36%) | called by muse, mutect2, varscan2
- MYO15A | c.3197C>T p.A1066V | Missense Mutation (SNP) | VAF 31/47 reads (66%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYO5B | c.2737G>A p.A913T | Missense Mutation (SNP) | VAF 37/50 reads (74%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MYO9B | c.5387A>T p.E1796V | Missense Mutation (SNP) | VAF 63/147 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NAA35 | c.412C>G p.P138A | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- NAV3 | c.255C>G p.D85E | Missense Mutation (SNP) | VAF 52/106 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- NBEAL1 | c.5907dup p.E1970Rfs*3 | Frame Shift Ins (INS) | VAF 10/39 reads (26%) | called by pindel, varscan2
- NBEAL1 | c.5908G>A p.E1970K | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.227); called by muse, varscan2
- NCAN | c.1706del p.P569Lfs*19 | Frame Shift Del (DEL) | VAF 9/30 reads (30%) | called by mutect2, pindel, varscan2
- NCAPD2 | c.1126G>C p.V376L | Missense Mutation (SNP) | VAF 107/137 reads (78%) | SIFT deleterious (0.01); PolyPhen benign (0.049); called by muse, varscan2
- NCAPD3 | c.2672A>G p.H891R | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.127); called by muse, mutect2
- NCOA1 | c.1579A>G p.N527D | Missense Mutation (SNP) | VAF 76/157 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, varscan2
- NDST2 | c.1378T>C p.Y460H | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- NDUFS2 | c.108G>T p.Q36H | Missense Mutation (SNP) | VAF 10/145 reads (7%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2
- NEFM | c.1988A>G p.E663G | Missense Mutation (SNP) | VAF 120/162 reads (74%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- NEK10 | c.2135T>C p.V712A | Missense Mutation (SNP) | VAF 53/67 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- NF1 | c.1067T>A p.L356Q | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NKAPD1 | c.763_766del p.E255Kfs*7 (on ENST00000280352 / NM_001082970.2; = p.E256Kfs*7 on NM_018195.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 18/26 reads (69%) | called by mutect2, pindel, varscan2
- NLRC5 | c.1244G>A p.C415Y | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- NLRC5 | c.3674G>A p.C1225Y | Missense Mutation (SNP) | VAF 80/95 reads (84%) | SIFT deleterious (0); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- NLRP8 | c.2163G>C p.K721N | Missense Mutation (SNP) | VAF 70/134 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- NNT | c.672dup p.V225Sfs*5 | Frame Shift Ins (INS) | VAF 8/26 reads (31%) | called by mutect2, pindel, varscan2
- NOP14 | c.1635+1G>T p.X545_splice | Splice Site (SNP) | VAF 49/88 reads (56%) | called by muse, mutect2, varscan2
- NOX5 | c.1463A>G p.E488G | Missense Mutation (SNP) | VAF 72/146 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPHP1 | c.1528C>T p.L510F (on ENST00000393272 / NM_207181.4; = p.L511F on NM_000272.5) | Missense Mutation (SNP) | VAF 72/101 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NR2F1 | c.683T>C p.F228S | Missense Mutation (SNP) | VAF 113/269 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- NR3C2 | c.2624T>C p.L875S | Missense Mutation (SNP) | VAF 38/52 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRK | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 16/233 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NRK | c.1603G>A p.A535T | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.037); called by muse, mutect2
- NUP205 | c.676C>T p.Q226* | Nonsense Mutation (SNP) | VAF 40/101 reads (40%) | called by muse, mutect2, varscan2
- ODAM | c.659A>G p.E220G | Missense Mutation (SNP) | VAF 68/168 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR10K2 | c.895T>A p.S299T | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR1B1 | c.754A>T p.T252S | Missense Mutation (SNP) | VAF 52/127 reads (41%) | SIFT tolerated (1); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- OR1M1 | c.619A>T p.I207L | Missense Mutation (SNP) | VAF 52/107 reads (49%) | SIFT tolerated (0.63); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- OR2F2 | c.427A>G p.R143G | Missense Mutation (SNP) | VAF 126/314 reads (40%) | SIFT tolerated (0.63); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- OR4K15 | c.678T>A p.D226E (on ENST00000305051; = p.D202E on NM_001005486.1) | Missense Mutation (SNP) | VAF 56/119 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- OR5AU1 | c.435dup p.V146Cfs*20 | Frame Shift Ins (INS) | VAF 45/126 reads (36%) | called by mutect2, pindel, varscan2
- OR7A17 | c.728C>T p.S243L | Missense Mutation (SNP) | VAF 61/164 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- OSBPL11 | c.361C>T p.H121Y | Missense Mutation (SNP) | VAF 30/40 reads (75%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- OTOF | c.1059T>A p.H353Q | Missense Mutation (SNP) | VAF 94/222 reads (42%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.478); called by muse, varscan2
- OTOGL | c.2156C>T p.A719V (on ENST00000547103; = p.A710V on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- OTOGL | c.2537G>A p.G846E (on ENST00000547103; = p.G837E on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 74/163 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- OXCT1 | c.1504A>G p.T502A | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PAGR1 | c.105T>A p.D35E | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- PAIP1 | c.772A>G p.K258E | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- PAK3 | c.677C>A p.A226D (on ENST00000262836 / NM_001324328.2; = p.A211D on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/83 reads (88%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- PAM | c.1777dup p.W593Lfs*18 | Frame Shift Ins (INS) | VAF 84/224 reads (38%) | called by mutect2, varscan2
- PAPOLA | c.2067+2T>C p.X689_splice | Splice Site (SNP) | VAF 43/124 reads (35%) | called by muse, mutect2, varscan2
- PARP1 | c.950C>T p.A317V | Missense Mutation (SNP) | VAF 14/302 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); called by muse, mutect2
- PATZ1 | c.116G>T p.R39L | Missense Mutation (SNP) | VAF 112/214 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- PCED1B | c.618del p.K206Nfs*231 | Frame Shift Del (DEL) | VAF 26/86 reads (30%) | called by mutect2, pindel, varscan2
- PCNX1 | c.3266G>A p.S1089N | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PDCD10 | c.172C>G p.L58V | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0.04); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- PDCD6IP | c.1302T>G p.D434E | Missense Mutation (SNP) | VAF 163/225 reads (72%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDGFRA | c.2614T>G p.Y872D | Missense Mutation (SNP) | VAF 77/166 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDGFRB | c.1345T>C p.S449P | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- PDILT | c.1237+2T>A p.X413_splice | Splice Site (SNP) | VAF 45/98 reads (46%) | called by muse, mutect2
- PDS5B | c.3598A>C p.K1200Q | Missense Mutation (SNP) | VAF 33/43 reads (77%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- PER3 | c.2195C>T p.A732V | Missense Mutation (SNP) | VAF 93/178 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- PFKL | c.1790A>G p.D597G | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- PHETA2 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); called by muse, mutect2
- PHF7 | c.1031C>G p.T344S | Missense Mutation (SNP) | VAF 141/174 reads (81%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- PHKB | c.701T>G p.L234R | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- PHRF1 | c.3169_3179dup p.S1060Rfs*143 (on ENST00000264555 / NM_001286581.2; = p.S1059Rfs*143 on NM_020901.4) | Frame Shift Ins (INS) | VAF 39/72 reads (54%) | called by mutect2, varscan2
- PHYKPL | c.777C>A p.F259L | Missense Mutation (SNP) | VAF 179/403 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- PI4KA | c.799G>T p.E267* | Nonsense Mutation (SNP) | VAF 16/53 reads (30%) | called by muse, mutect2, varscan2
- PIFO | c.163T>A p.Y55N | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PIGG | c.2674T>C p.Y892H (on ENST00000453061 / NM_001127178.3; = p.Y884H on NM_017733.4) | Missense Mutation (SNP) | VAF 96/273 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- PIH1D2 | c.151C>A p.Q51K | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2
- PITRM1 | c.736A>T p.T246S | Missense Mutation (SNP) | VAF 72/158 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- PKD1L1 | c.124T>C p.C42R | Missense Mutation (SNP) | VAF 124/307 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- PKDREJ | c.4387T>C p.S1463P | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PKHD1L1 | c.5121T>A p.Y1707* | Nonsense Mutation (SNP) | VAF 54/76 reads (71%) | called by muse, mutect2, varscan2
- PKN3 | c.817A>T p.K273* | Nonsense Mutation (SNP) | VAF 23/52 reads (44%) | called by muse, mutect2, varscan2
- PLA2G4A | c.703T>C p.S235P | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLCE1 | c.2959C>T p.H987Y | Missense Mutation (SNP) | VAF 103/188 reads (55%) | SIFT tolerated (0.42); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PLPP2 | c.173C>A p.A58D | Missense Mutation (SNP) | VAF 96/292 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- PNPLA6 | c.3410A>G p.Y1137C (on ENST00000414982 / NM_001166111.2; = p.Y1089C on NM_006702.5) | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- POLG | c.2932G>A p.A978T | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POLR1F | c.587del p.G196Efs*3 | Frame Shift Del (DEL) | VAF 24/60 reads (40%) | called by mutect2, varscan2
- POLR2H | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 71/95 reads (75%) | SIFT tolerated (0.1); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- PPA1 | c.653A>T p.D218V | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- PPARA | c.1018A>G p.T340A | Missense Mutation (SNP) | VAF 90/219 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- PPP2R3C | c.119C>G p.S40C | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP4R3A | c.2183del p.K728Rfs*5 (on ENST00000554943 / NM_001366432.1; = p.K715Rfs*5 on NM_001284280.1) | Frame Shift Del (DEL) | VAF 34/100 reads (34%) | called by mutect2, pindel, varscan2
- PPP6R1 | c.2480C>T p.T827I | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PPRC1 | c.1744G>A p.A582T | Missense Mutation (SNP) | VAF 87/217 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- PRDM5 | c.1843G>A p.D615N | Missense Mutation (SNP) | VAF 37/53 reads (70%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PRRC2B | c.6235C>T p.P2079S | Missense Mutation (SNP) | VAF 75/172 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- PRTG | c.127A>T p.K43* | Nonsense Mutation (SNP) | VAF 39/76 reads (51%) | called by muse, mutect2
- PSG6 | c.801C>A p.N267K | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- PSG7 | c.180G>T p.Q60H | Missense Mutation (SNP) | VAF 96/202 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PSMB1 | c.45G>T p.L15F | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- PSMB3 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 73/97 reads (75%) | SIFT tolerated (0.49); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- PTBP3 | c.1573G>A p.A525T | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRZ1 | c.135T>A p.N45K | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAB34 | c.745A>G p.T249A | Missense Mutation (SNP) | VAF 89/110 reads (81%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAET1L | c.134C>A p.P45H | Missense Mutation (SNP) | VAF 106/384 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- RAMP3 | c.223del p.M75Wfs*48 | Frame Shift Del (DEL) | VAF 19/57 reads (33%) | called by mutect2, pindel, varscan2
- RAPGEF6 | c.4056T>A p.H1352Q | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- RBM27 | c.1448C>A p.T483K | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- RBM43 | c.750_751dup p.K251Rfs*12 | Frame Shift Ins (INS) | VAF 14/41 reads (34%) | called by mutect2, pindel, varscan2
- RCOR3 | c.547-1G>A p.X183_splice | Splice Site (SNP) | VAF 76/194 reads (39%) | called by muse, mutect2, varscan2
- REPS1 | c.1639C>G p.P547A (on ENST00000450536 / NM_001286611.2; = p.P546A on NM_031922.4) | Missense Mutation (SNP) | VAF 78/155 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RGS10 | c.512A>T p.Y171F (on ENST00000369101; = p.Y165F on NM_002925.3) | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); called by muse, varscan2
- RHOT1 | c.1621T>C p.S541P | Missense Mutation (SNP) | VAF 50/70 reads (71%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RIMKLB | c.917T>C p.L306P | Missense Mutation (SNP) | VAF 70/89 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- RIMS1 | c.2428A>G p.N810D | Missense Mutation (SNP) | VAF 57/125 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RIMS1 | c.3610C>T p.Q1204* | Nonsense Mutation (SNP) | VAF 44/114 reads (39%) | called by muse, mutect2, varscan2
- RNF19A | c.521T>C p.I174T | Missense Mutation (SNP) | VAF 39/46 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- RNF31 | c.1204del p.D402Mfs*90 | Frame Shift Del (DEL) | VAF 58/129 reads (45%) | called by mutect2, varscan2
- RORA | c.460_461del p.D154Qfs*26 (on ENST00000335670 / NM_134261.3; = p.D179Qfs*26 on NM_002943.3) | Frame Shift Del (DEL) | VAF 62/192 reads (32%) | called by pindel, varscan2
- RPS6KC1 | c.293G>T p.R98I | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- RRP9 | c.1199T>C p.V400A | Missense Mutation (SNP) | VAF 168/224 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.427); called by muse, mutect2, varscan2
- RUVBL2 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 70/137 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- RYR1 | c.14395A>C p.M4799L | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- SCAF4 | c.1802A>T p.Y601F | Missense Mutation (SNP) | VAF 59/156 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SCAP | c.2947G>T p.G983W | Missense Mutation (SNP) | VAF 39/49 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCN11A | c.3377A>T p.D1126V | Missense Mutation (SNP) | VAF 30/48 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCN7A | c.252del p.N84Kfs*42 | Frame Shift Del (DEL) | VAF 11/40 reads (28%) | called by mutect2, pindel, varscan2
- SDHA | c.1301G>A p.G434D | Missense Mutation (SNP) | VAF 179/423 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SDK1 | c.6292G>A p.D2098N | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SEC24B | c.3782A>G p.H1261R | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- SEC31A | c.546T>A p.H182Q | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- SERPINA3 | c.1007C>T p.A336V | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SERPINA6 | c.913A>G p.T305A | Missense Mutation (SNP) | VAF 66/122 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SERPINB1 | c.511T>C p.W171R | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SETD5 | c.1721T>A p.V574D | Missense Mutation (SNP) | VAF 41/45 reads (91%) | SIFT tolerated (0.51); PolyPhen benign (0.015); called by muse, mutect2, varscan2
442 further variants in this file (130 protein-altering or splice-affecting, 291 silent, 21 other) are not listed here.
